Somatic mutation profile of tumor specimen MMRF_1778_1_PB_CD138pos (aliquot MMRF_1778_1_PB_CD138pos_T3_KBS5U_K11893) from MMRF case MMRF_1778, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,272 days).
Specimen MMRF_1778_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8bd2d3c-983b-49e8-b13a-38f17cb5ef76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1778_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1778_1_PB_CD3pos_C2_KBS5U_K11909; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c2b083e-20ac-4366-9386-2dff7f5c507a

The open-access MAF lists 66 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 17, Intron 9, Silent 6, 5'UTR 4, 5'Flank 4, Nonsense Mutation 2, RNA 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C11 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100137751, COSV58899594; called by muse, mutect2, varscan2
- HMGXB3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1004708591; called by muse, mutect2, varscan2
- IGSF9B | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58065229; called by muse, mutect2, varscan2
- IKBKB | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100645808, COSV60598802, COSV60598896; called by muse, mutect2, varscan2
- JAK3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV71685401; called by muse, mutect2, varscan2
- PIGR | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as rs767071176; called by muse, mutect2, varscan2
- PPIE | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1054552682; called by muse, mutect2, varscan2
- SLC6A2 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54923281; called by mutect2, varscan2
- SPHK1 | c.625C>T p.R209* (on ENST00000392496 / NM_001355139.2; = p.R223* on NM_021972.4) | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs1185092590; called by mutect2, varscan2
- UTP18 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs539214309, COSV56583294; called by muse, mutect2, varscan2
- YEATS4 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1464980352; called by muse, mutect2, varscan2
- CACNA1H | c.6635G>A p.G2212D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CAPZA2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CSMD3 | c.9905G>A p.R3302K (on ENST00000297405 / NM_001363185.1; = p.R3133K on NM_052900.3) | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CYP51A1 | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CYTH3 | c.1111_1113del p.E371del (on ENST00000396741; = p.E370del on NM_004227.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 22/46 reads (48%) | called by pindel, varscan2
- HOOK2 | c.1844A>T p.E615V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- LPP | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- MOB1B | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- PPM1K | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SIM1 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF3 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- UBR4 | c.13314G>A p.M4438I | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ZNF134 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGBL4 | c.807C>T p.L269= | Silent (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- GKN1 | c.126C>G p.V42= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as COSV100933563; called by muse, mutect2, varscan2
- PCDHA2 | c.1869C>T p.R623= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs1554120147; called by muse, mutect2, varscan2
- PRL | c.367C>T p.L123= | Silent (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- SLC22A15 | c.114C>T p.L38= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- WDR88 | c.948G>A p.L316= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- ADAM12 | c.*4136G>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- AK9 | c.3633+1121T>C | Intron (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2
- ANKRD13A | c.*1861G>A | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8444C>G | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- ARL10 | c.*871G>A | 3'UTR (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- CCDC73 | c.429+1412T>A | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CD44 | c.*1772C>G | 3'UTR (SNP) | VAF 35/42 reads (83%) | called by muse, mutect2, varscan2
- CRACR2B | c.*79C>T | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- DCN | c.885+593C>T | Intron (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*1635_*1645del | 3'UTR (DEL) | VAF 37/48 reads (77%) | called by mutect2, varscan2
- EFCAB14 | c.987+73G>C | Intron (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- EFNB2 | c.*1379G>T | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- EIF5 | c.-208-526T>C | Intron (SNP) | VAF 7/85 reads (8%) | catalogued as rs1416448113; called by muse, mutect2
- FAT1 | c.12369-24C>G | Intron (SNP) | VAF 11/95 reads (12%) | called by mutect2, varscan2
- FBXW11 | chr5:172006708 C>A | 5'Flank (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- FCMR | c.*1619G>A | 3'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- GABRG1 | c.*4121C>T | 3'UTR (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- GPR132 | c.*48C>T | 3'UTR (SNP) | VAF 40/46 reads (87%) | called by muse, mutect2, varscan2
- HYDIN2 | n.5485C>T | RNA (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- IRF6 | c.*2595C>T | 3'UTR (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- KCNMA1 | chr10:77638137 G>T | 5'Flank (SNP) | VAF 51/132 reads (39%) | catalogued as rs933872661; called by muse, varscan2
- LILRB5 | c.1576+91del | Intron (DEL) | VAF 8/30 reads (27%) | catalogued as rs1190773258; called by mutect2, varscan2
- LNPEP | c.*5783C>T | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- MPZL1 | c.*448G>C | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62246587 C>T | 5'Flank (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- NLN | c.*3264G>C | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- NUAK1 | c.*1867C>T | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- PCDHB9 | chr5:141187150 A>C | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- PHF13 | c.-98C>T | 5'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- PLRG1 | c.*400G>A | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- PROB1 | c.-1C>G | 5'UTR (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- RNF113B | c.-24C>A | 5'UTR (SNP) | VAF 25/51 reads (49%) | catalogued as COSV99940332; called by muse, mutect2, varscan2
- SOS2 | c.*351G>A | 3'UTR (SNP) | VAF 29/68 reads (43%) | catalogued as rs1299738137; called by muse, mutect2, varscan2
- STARD7 | c.-31G>A | 5'UTR (SNP) | VAF 7/16 reads (44%) | catalogued as rs1043382879; called by muse, mutect2, varscan2
- SYNCRIP | chr6:85611814 A>C | 3'Flank (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- TUFT1 | c.415-39C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
